Somatic mutation profile of tumor specimen TCGA-BR-7723-01A (aliquot TCGA-BR-7723-01A-11D-2053-08) from TCGA case TCGA-BR-7723, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 59.8 years (21,839 days).
Specimen TCGA-BR-7723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a11f43e-3191-44a1-bf3a-0c23c8785313.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7723-10A (Blood Derived Normal), aliquot TCGA-BR-7723-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2129a3eb-77cf-4022-b7c7-64b8499b700e

The open-access MAF lists 179 somatic variants for this specimen: 128 protein-altering or splice-affecting, 45 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 45, Nonsense Mutation 7, Splice Site 5, Intron 3, RNA 3, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-1G>A p.X261_splice | Splice Site (SNP) | VAF 7/9 reads (78%) | hotspot (GDC flag); catalogued as rs1555525367, CS137625, COSV52668714, COSV52729930, COSV53769335; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACCSL | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66581675; called by muse, mutect2, varscan2
- ACSM2B | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV61658602; called by muse, mutect2, varscan2
- ACTRT1 | c.208T>G p.L70V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV100947490, COSV64419660; called by muse, mutect2, varscan2
- ADCY2 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57881290; called by muse, mutect2, varscan2
- ADGRL4 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100875652, COSV66059752; called by muse, mutect2, varscan2
- ADGRV1 | c.16852A>G p.T5618A | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67988818; called by muse, mutect2, varscan2
- ADRA1A | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV52367644; called by muse, mutect2, varscan2
- AHNAK | c.3308T>C p.I1103T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV57218421; called by muse, mutect2, varscan2
- AL592490.1 | c.2336T>C p.V779A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.191); catalogued as COSV69426809; called by muse, mutect2, varscan2
- ANK2 | c.11825G>A p.R3942H | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs542400709, COSV52170394; called by muse, mutect2, varscan2
- ARHGAP20 | c.2570T>C p.L857P | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52814157; called by muse, mutect2, varscan2
- ARMC4 | c.2304G>T p.Q768H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59466686; called by muse, mutect2, varscan2
- ASCC3 | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV61230498; called by muse, mutect2, varscan2
- BCO2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs149163526; called by muse, mutect2, varscan2
- BRCA2 | c.9785A>C p.Q3262P | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1566261012, COSV66337584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.9937A>C p.K3313Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV66337590; called by muse, mutect2, varscan2
- C19orf33 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.447); catalogued as COSV56651086; called by muse, mutect2, varscan2
- C4BPA | c.1649T>C p.L550P | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.733); catalogued as COSV65536742; called by muse, mutect2, varscan2
- CCDC191 | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55673628; called by muse, mutect2, varscan2
- CCDC38 | c.1142+1G>C p.X381_splice | Splice Site (SNP) | VAF 8/56 reads (14%) | catalogued as COSV60183701; called by muse, mutect2, varscan2
- CD1C | c.315A>T p.Q105H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV63806845, COSV63807795, COSV63807967; called by muse, mutect2, varscan2
- CD1E | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100937010, COSV63770217; called by muse, mutect2
- CD33 | c.72A>T p.Q24H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV51802759; called by muse, mutect2
- CENPH | c.487+1G>A p.X163_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as rs541394077, COSV51585132; called by muse, mutect2, varscan2
- CEP83 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60409250; called by muse, mutect2, varscan2
- CLSTN1 | c.1844C>T p.T615M (on ENST00000377298 / NM_001009566.3; = p.T605M on NM_014944.4) | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424803630, COSV63647855; called by muse, mutect2, varscan2
- CNOT1 | c.1423T>G p.F475V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV57773117, COSV57773754; called by muse, mutect2, varscan2
- COL6A5 | c.6917A>T p.E2306V (on ENST00000312481; = p.E2302V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV99591768, COSV99592916; called by muse, mutect2, varscan2
- COL6A6 | c.5033A>T p.E1678V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV62029275; called by muse, mutect2, varscan2
- CSGALNACT1 | c.602A>G p.H201R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV59979567; called by muse, mutect2, varscan2
- CTDSPL2 | c.1360A>G p.R454G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV52946953; called by muse, mutect2, varscan2
- DGKA | c.1187A>C p.K396T | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59386925; called by muse, mutect2, varscan2
- DOCK2 | c.3065A>C p.E1022A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56968190; called by muse, mutect2, varscan2
- DPY19L4 | c.1700T>C p.L567P | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68963219; called by muse, mutect2, varscan2
- DUSP23 | c.436T>G p.Y146D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV100929110; called by muse, mutect2, varscan2
- DZIP1L | c.115A>C p.S39R | Missense Mutation (SNP) | VAF 161/295 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59521970; called by muse, mutect2, varscan2
- EDNRB | c.50G>A p.W17* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100526167; called by muse, mutect2, varscan2
- ELAVL2 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV56364794, COSV56365714; called by muse, mutect2, varscan2
- EXPH5 | c.2704T>A p.S902T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV56204267; called by muse, mutect2, varscan2
- FAM89B | c.494C>T p.P165L (on ENST00000530349 / NM_001098785.2; = p.P152L on NM_152832.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1051879804, COSV57079731, COSV57080195; called by muse, mutect2, varscan2
- FANCD2 | c.1276T>C p.L426= | Splice Region (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99810245; called by muse, mutect2, varscan2
- FBLN2 | c.1787T>C p.L596P | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.854); catalogued as COSV55486794; called by muse, mutect2, varscan2
- FLG2 | c.6529A>G p.R2177G | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV66169911; called by muse, mutect2, varscan2
- FLNA | c.4010G>T p.G1337V | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV61046320; called by muse, varscan2
- FSHR | c.58C>A p.H20N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.668); catalogued as COSV58627211; called by muse, mutect2, varscan2
- FSTL1 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV55234548; called by muse, mutect2, varscan2
- GINS4 | c.537A>C p.Q179H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV52531754; called by muse, mutect2, varscan2
- GPX2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755670449, COSV63036427; called by muse, mutect2, varscan2
- GRM2 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs534825087, COSV56585726; called by muse, mutect2, varscan2
- HHIPL2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs375371391; called by muse, mutect2, varscan2
- HSF2 | c.572T>G p.L191R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV63774128; called by muse, mutect2, varscan2
- HSPBAP1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs371225480; called by muse, mutect2, varscan2
- IGFN1 | c.2038G>A p.V680M (on ENST00000295591 / NM_001367841.1; = p.V3137M on NM_001164586.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.49); catalogued as rs367699515, COSV55176279; called by muse, mutect2, varscan2
- IL1RAPL2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as COSV61165123; called by muse, mutect2, varscan2
- KCNK15 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65729773; called by muse, mutect2
- KCNQ5 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs747182315, COSV59662050; called by muse, mutect2, varscan2
- KIF2B | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs369005833, COSV52129723; called by muse, mutect2, varscan2
- KSR2 | c.2583C>A p.G861= | Splice Region (SNP) | VAF 9/62 reads (15%) | catalogued as COSV56676617; called by muse, varscan2
- LAMA5 | c.1693G>T p.G565C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99437787; called by muse, mutect2, varscan2
- LILRB5 | c.1579G>A p.A527T (on ENST00000449561 / NM_001081442.3; = p.A526T on NM_006840.5) | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs1192804914, COSV60258896; called by muse, mutect2, varscan2
- LRP1B | c.1435C>G p.P479A | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV67184445, COSV67241706; called by muse, mutect2, varscan2
- LRRC37B | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100495981; called by muse, mutect2, varscan2
- LRRIQ3 | c.367A>C p.T123P | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV63045962; called by muse, mutect2, varscan2
- MAGEB18 | c.498A>C p.E166D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57463531; called by muse, mutect2, varscan2
- MAP3K3 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as COSV100675422, COSV100675548; called by muse, mutect2, varscan2
- MEX3B | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV61663576; called by muse, mutect2, varscan2
- MEX3C | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778380833, COSV68530166; called by muse, mutect2, varscan2
- MYO1H | c.1016T>G p.I339S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60447544, COSV60448881; called by muse, mutect2, varscan2
- NELFB | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV58025561; called by muse, mutect2, varscan2
- NINL | c.1104G>A p.M368I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV54004523; called by muse, mutect2, varscan2
- NPAP1 | c.656A>T p.N219I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV61508453; called by muse, mutect2, varscan2
- NR5A2 | c.1316G>A p.R439H (on ENST00000367362 / NM_205860.3; = p.R393H on NM_003822.5) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.112); catalogued as rs1182541887, COSV52648273, COSV52648662; called by muse, mutect2, varscan2
- NXPE3 | c.1536G>A p.M512I | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.113); catalogued as COSV56290640; called by muse, mutect2, varscan2
- OR14A16 | c.533A>T p.D178V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62926928; called by muse, mutect2, varscan2
- OR1B1 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1260103936, COSV59171936; called by muse, mutect2, varscan2
- OR2D2 | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV55057496; called by muse, mutect2, varscan2
- OR2M5 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as rs761884640, COSV100822723, COSV63546556; called by muse, varscan2
- OR2T1 | c.178T>G p.F60V | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV63541764, COSV63542319; called by muse, mutect2, varscan2
- OR51E1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200993659, COSV67810326; called by muse, mutect2, varscan2
- PAQR9 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61418538; called by muse, mutect2, varscan2
- PARP10 | c.1049G>C p.S350T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV57298729; called by muse, mutect2, varscan2
- PCDHB9 | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV53380744; called by muse, mutect2, varscan2
- PCLO | c.12736A>G p.R4246G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100427029; called by muse, mutect2, varscan2
- PCLO | c.6063T>G p.H2021Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.51); catalogued as COSV61645491; called by muse, mutect2, varscan2
- PFKP | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.09); catalogued as rs746311349, COSV66899291; called by muse, mutect2, varscan2
- PLXND1 | c.5309G>A p.R1770Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV60710146, COSV60715557; called by muse, mutect2, varscan2
- POMGNT2 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV60953861; called by muse, mutect2, varscan2
- PPP1R13L | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62908683; called by muse, mutect2, varscan2
- PPP1R16A | c.251T>A p.L84Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52953686; called by muse, mutect2, varscan2
- PRKCG | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.634); catalogued as rs551805527, COSV54729602; ClinVar: likely benign; called by muse, mutect2, varscan2
- PROKR1 | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV58138138; called by muse, mutect2, varscan2
- PTCD1 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52864894; called by muse, mutect2, varscan2
- RAI2 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs993591280, COSV100518309, COSV58963582; called by muse, mutect2, varscan2
- RAPGEF6 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV57249390; called by muse, mutect2, varscan2
- ROBO1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.956); catalogued as COSV71970043; called by muse, mutect2, varscan2
- RPE | c.685T>C p.*229Rext*69 (on ENST00000359429 / NM_001318926.1; = p.*179Rext*69 on NM_006916.2) | Nonstop Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55993771; called by muse, mutect2
- SC5D | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV50613194; called by muse, varscan2
- SCGB1D4 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 54/268 reads (20%) | catalogued as rs752348321, COSV62204135; called by muse, mutect2, varscan2
- SCN3A | c.2635G>T p.V879L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.644); catalogued as COSV51814824; called by muse, mutect2
- SCN4A | c.3058C>G p.L1020V | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.447); catalogued as rs371779795, COSV71127525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.4193G>A p.W1398* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101268718; called by muse, mutect2, varscan2
- SYNE1 | c.21101T>A p.L7034Q (on ENST00000367255 / NM_182961.4; = p.L6963Q on NM_033071.3) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55022610; called by muse, mutect2, varscan2
- TBPL2 | c.1117A>T p.K373* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as rs767811298, COSV55955610; called by muse, mutect2, varscan2
- TG | c.1738T>G p.F580V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as COSV99598782; called by muse, mutect2, varscan2
- TMEM225 | c.383A>G p.Q128R | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV66693630; called by muse, mutect2, varscan2
- TNNI3K | c.2200A>C p.S734R | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.986); catalogued as COSV53946162; called by muse, mutect2, varscan2
- TPD52L3 | c.11C>A p.A4D | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV58828534; called by muse, mutect2, varscan2
- TPO | c.1927T>C p.F643L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as COSV61094323; called by muse, mutect2
- UNC79 | c.3082G>A p.V1028I (on ENST00000393151 / NM_001346218.2; = p.V851I on NM_020818.5) | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs139389360; called by muse, mutect2, varscan2
- USP13 | c.1503A>T p.L501F | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55867261; called by muse, mutect2, varscan2
- WNK4 | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as rs1387533241, COSV55906589; called by muse, mutect2, varscan2
- XDH | c.2876A>C p.K959T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as COSV101052525, COSV65147660; called by muse, mutect2, varscan2
- XYLT2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50018991; called by muse, mutect2, varscan2
- ZDBF2 | c.5051A>G p.H1684R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65627559; called by muse, mutect2, varscan2
- ZEB2 | c.2895G>T p.L965F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100354869; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs563751025; called by mutect2, varscan2
- ZNF211 | c.767T>A p.L256H (on ENST00000347302 / NM_198855.4; = p.L269H on NM_006385.5) | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.927); catalogued as COSV53743259; called by muse, mutect2
- ZNF345 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1208411183, COSV59324381; called by muse, mutect2, varscan2
- ZNF623 | c.1334A>G p.K445R | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs1373170478, COSV71697252; called by muse, mutect2
- ZNF682 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as rs1475114737, COSV62067652; called by muse, mutect2, varscan2
- ZSCAN4 | c.492A>C p.Q164H | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV56593645; called by muse, mutect2, varscan2
- IGKV1-8 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- LBR | c.1562_1564+10del p.X521_splice | Splice Site (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- LINC02210-CRHR1 | c.245+3_245+6del p.X82_splice | Splice Site (DEL) | VAF 9/57 reads (16%) | called by pindel, varscan2
- MAGEB6B | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NAV3 | c.6968del p.S2323Tfs*24 (on ENST00000397909 / NM_001024383.2; = p.S2301Tfs*24 on NM_014903.6) | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel, varscan2
- PNRC2 | c.352dup p.S118Ffs*3 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD42 | c.816T>A p.T272= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as COSV52616769; called by muse, mutect2, varscan2
- BCO1 | c.1176A>G p.Q392= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV50730517; called by muse, mutect2, varscan2
- BIRC6 | c.8574C>T p.A2858= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs550913772, COSV70196776; called by muse, mutect2, varscan2
- CYP11A1 | c.102T>C p.T34= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51432933, COSV99165979; called by muse, mutect2, varscan2
- FTCD | c.165G>A p.P55= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs143451664; called by muse, mutect2, varscan2
- GIGYF1 | c.1830G>A p.T610= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs138722511, COSV51943749; called by muse, mutect2, varscan2
- GJA8 | c.1185G>T p.G395= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV53789357; called by muse, mutect2
- IGF1R | c.795G>A p.P265= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs565401892, COSV51307996; called by muse, mutect2, varscan2
- IMPG2 | c.3048T>C p.F1016= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV51980792; called by muse, mutect2, varscan2
- IRX5 | c.1056C>G p.G352= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV58059352, COSV58059502; called by muse, mutect2, varscan2
- KIDINS220 | c.2376A>G p.R792= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99874848; called by mutect2, varscan2
- KRI1 | c.1695G>A p.E565= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs1304395354, COSV100469858, COSV57263623; called by muse, mutect2, varscan2
- KRT73 | c.456C>T p.F152= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV59840067; called by muse, mutect2, varscan2
- MAGEB6B | c.774C>T p.S258= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as rs751739511; called by muse, mutect2, varscan2
- MTSS2 | c.1830G>A p.A610= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs144949231; called by muse, mutect2, varscan2
- MUC5B | c.8964G>A p.G2988= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as rs552609450, COSV71593678; called by muse, mutect2, varscan2
- NDNF | c.1554C>T p.F518= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV65633997; called by muse, mutect2
- NOD1 | c.1911C>T p.R637= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs994480424, COSV56113384; called by muse, mutect2
- OR2B11 | c.468C>A p.G156= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV100276575, COSV59510610; called by muse, mutect2, varscan2
- OR2F1 | c.429G>A p.R143= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV67331617; called by muse, mutect2, varscan2
- PARP10 | c.1560C>T p.S520= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs371073478; called by muse, mutect2, varscan2
- PDGFC | c.198T>G p.T66= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56850005; called by muse, mutect2, varscan2
- PITPNM3 | c.1479G>T p.R493= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV52593471; called by mutect2, varscan2
- PKD1L1 | c.4710G>A p.R1570= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV56969814; called by muse, mutect2, varscan2
- PRB2 | c.267T>C p.P89= | Silent (SNP) | VAF 46/326 reads (14%) | catalogued as rs758143951, COSV66982772, COSV66983518; called by muse, mutect2, varscan2
- PRSS36 | c.693C>T p.Y231= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV51638213; called by muse, mutect2, varscan2
- PXK | c.840T>C p.H280= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV57090495; called by muse, mutect2, varscan2
- RBBP8 | c.228C>A p.T76= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV100507019; called by muse, mutect2, varscan2
- REV3L | c.2838T>A p.P946= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV62620515; called by muse, mutect2, varscan2
- RHCG | c.564C>T p.G188= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs772093651, COSV51514536; called by muse, mutect2, varscan2
- RIMS1 | c.3168G>A p.Q1056= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1489346752, COSV53454182; called by muse, mutect2
- RYR1 | c.7356G>A p.R2452= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV100615486, COSV62101821; called by muse, mutect2, varscan2
- SBNO1 | c.3522C>T p.H1174= (on ENST00000420886; = p.H1173= on NM_018183.5) | Silent (SNP) | VAF 42/272 reads (15%) | catalogued as rs376953957, COSV57339034; called by muse, varscan2
- SLCO1C1 | c.1089T>A p.T363= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV56875019, COSV56880891; called by muse, mutect2, varscan2
- SP8 | c.741G>A p.P247= (on ENST00000361443 / NM_198956.4; = p.P265= on NM_182700.6) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1160686807, COSV63866039; called by muse, mutect2, varscan2
- ST6GAL2 | c.567C>T p.G189= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV64529493; called by muse, mutect2, varscan2
- TACC2 | c.1281T>A p.A427= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV57761072; called by muse, mutect2, varscan2
- TENM1 | c.486A>G p.K162= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV64435772; called by muse, mutect2, varscan2
- TOGARAM1 | c.1677A>G p.Q559= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs781263117, COSV61888599; called by muse, mutect2, varscan2
- TPH1 | c.69C>G p.S23= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV51458808; called by muse, mutect2
- TTLL1 | c.993G>A p.P331= | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as rs143499869; called by muse, mutect2, varscan2
- TTN | c.92265T>A p.I30755= (on ENST00000591111; = p.I23331= on NM_003319.4) | Silent (SNP) | VAF 68/206 reads (33%) | catalogued as COSV60159593; called by muse, mutect2, varscan2
- VCAN | c.1977T>A p.S659= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV54108866; called by muse, mutect2, varscan2
- VWA8 | c.574T>C p.L192= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as COSV55699586; called by muse, mutect2, varscan2
- ZC3H18 | c.1971C>T p.P657= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs376260255; called by muse, mutect2, varscan2
- AGBL4 | c.1267+57A>G | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- C3P1 | n.2478A>C | RNA (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- DST | c.4297-4101_4297-4092del | Intron (DEL) | VAF 29/139 reads (21%) | called by mutect2, pindel, varscan2
- MIR518D | n.32T>A | RNA (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- SNORD48 | n.25_26delinsC | RNA (DEL) | VAF 30/333 reads (9%) | called by mutect2*, pindel
- TRIM5 | c.895+128C>T | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99999945; called by muse, mutect2, varscan2
